Somatic mutation profile of tumor specimen TCGA-17-Z027-01A (aliquot TCGA-17-Z027-01A-01W-0746-08) from TCGA case TCGA-17-Z027, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be27e5a0-7124-4c6d-a5e4-59331bdc1cb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z027-11A (Solid Tissue Normal), aliquot TCGA-17-Z027-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f7cbb23-a6af-4410-93fa-88900bfe8ea7

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Nonsense Mutation 5, Frame Shift Ins 2, Intron 2, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 59/64 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1586T>A p.V529D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1211351410; called by muse, mutect2, varscan2
- ABI2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1279094325; called by muse, mutect2, varscan2
- ARL4A | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs779432324; called by muse, mutect2, varscan2
- ARSD | c.1563G>T p.R521S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs765801225; called by muse, mutect2
- ASGR2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 100/110 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs773007336; called by muse, mutect2, varscan2
- CHRNA2 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104382931; called by muse, mutect2, varscan2
- ELAVL3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 135/140 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs369938051; called by muse, mutect2, varscan2
- FRG2C | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV57316456; called by muse, mutect2, varscan2
- GCLC | c.593G>A p.R198K (on ENST00000643939; = p.R196K on NM_001498.4) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767501140; called by muse, mutect2, varscan2
- GDNF | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 151/460 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211866776; called by muse, mutect2, varscan2
- KCNH5 | c.2636G>C p.G879A | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as rs1489029574; called by muse, mutect2, varscan2
- LAMP2 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM068428; called by muse, mutect2, varscan2
- MCM6 | c.2367G>T p.E789D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1373219888; called by muse, mutect2, varscan2
- MYH15 | c.5309C>A p.A1770E | Missense Mutation (SNP) | VAF 128/181 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1388584907, COSV56305314; called by muse, mutect2, varscan2
- NCOR1 | c.886A>G p.R296G | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1394379058; called by muse, mutect2, varscan2
- NF1 | c.6563C>T p.S2188F (on ENST00000358273 / NM_001042492.3; = p.S2167F on NM_000267.3) | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1555534877, COSV62193815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSDHL | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.141); catalogued as rs868918302, COSV64744946; called by muse, mutect2, varscan2
- PLK3 | c.1493C>A p.S498* | Nonsense Mutation (SNP) | VAF 38/44 reads (86%) | catalogued as rs17880829, COSV100221322; called by muse, mutect2, varscan2
- POF1B | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1028934406; called by muse, mutect2, varscan2
- PRRG3 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64850827; called by muse, mutect2, varscan2
- RAX | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383068323; called by muse, varscan2
- RTL8B | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101195581, COSV66954243; called by muse, mutect2, varscan2
- RTP1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99044213; called by muse, mutect2, varscan2
- SLC13A3 | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV51714022; called by muse, mutect2, varscan2
- STXBP5L | c.2912T>C p.V971A | Missense Mutation (SNP) | VAF 81/123 reads (66%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV56504418; called by muse, mutect2, varscan2
- TSHR | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs530605964; called by muse, mutect2, varscan2
- ZBTB40 | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs756842699; called by muse, mutect2, varscan2
- ZNF107 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753360545, COSV100788317; called by muse, mutect2, varscan2
- ZNF831 | c.4511T>C p.I1504T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1479242786; called by muse, mutect2, varscan2
- ADAM15 | c.1756G>C p.G586R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAMTS16 | c.2407G>C p.V803L | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPM | c.10073G>A p.G3358D | Missense Mutation (SNP) | VAF 57/60 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C10orf71 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- CCDC28A | c.401A>C p.Y134S | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CDCA2 | c.1637A>G p.K546R | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CLDN9 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNOT3 | c.1240A>C p.S414R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMD | c.9640A>T p.K3214* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- DMD | c.6865G>C p.D2289H | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- DNASE1L1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ERGIC3 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FAM120B | c.995G>T p.S332I | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT3 | c.7121T>G p.L2374R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FBXO25 | c.821A>G p.Q274R (on ENST00000382824 / NM_183421.2; = p.Q207R on NM_012173.3) | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FNDC3B | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPRC6A | c.2365C>A p.L789I | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNS2 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 79/132 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT71 | c.524A>C p.N175T | Missense Mutation (SNP) | VAF 145/154 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- LCT | c.4315C>A p.L1439M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- LRFN2 | c.1265dup p.E423Gfs*8 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- LRRC7 | c.518C>G p.T173R (on ENST00000651989 / NM_001370785.2; = p.T140R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LSS | c.1989G>A p.R663= | Splice Region (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- MROH2B | c.2060A>C p.K687T | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEAL1 | c.6022G>T p.V2008L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- NFKB2 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 9/10 reads (90%) | called by muse, mutect2, varscan2
- NR1H2 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4C15 | c.449G>C p.C150S (on ENST00000314644; = p.C96S on NM_001001920.2) | Missense Mutation (SNP) | VAF 116/124 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PCDHB8 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PKD2 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- RO60 | c.277_280dup p.F94Sfs*21 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- RTL9 | c.3128C>A p.P1043Q | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SCN2A | c.2224T>A p.C742S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- SCN7A | c.2229T>G p.N743K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGO2 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC9A6 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SLFN5 | c.2429C>A p.A810E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMG1 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.4654T>G p.S1552A (on ENST00000367255 / NM_182961.4; = p.S1559A on NM_033071.3) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.214); called by mutect2, varscan2
- SYT10 | c.203T>A p.L68* | Nonsense Mutation (SNP) | VAF 56/60 reads (93%) | called by muse, mutect2, varscan2
- TAGAP | c.1410C>A p.D470E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TET3 | c.3308del p.K1103Rfs*79 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- U2SURP | c.2615A>T p.Q872L | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- USP16 | c.2027T>G p.V676G | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- WNK3 | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WNK3 | c.704T>C p.L235S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A2 | c.2856C>T p.G952= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1800241, COSV51959235; called by muse, mutect2, varscan2
- CXorf66 | c.231C>A p.S77= | Silent (SNP) | VAF 198/479 reads (41%) | called by muse, varscan2
- DISC1 | c.1845A>T p.T615= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs780245731; called by muse, mutect2
- DLC1 | c.1095T>A p.L365= | Silent (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- DLG2 | c.1299C>T p.F433= | Silent (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- DTL | c.1428C>G p.A476= | Silent (SNP) | VAF 69/76 reads (91%) | called by muse, mutect2, varscan2
- ERC1 | c.1863C>T p.A621= (on ENST00000360905 / NM_178040.4; = p.A593= on NM_178039.4) | Silent (SNP) | VAF 65/69 reads (94%) | called by muse, mutect2, varscan2
- GLA | c.933T>G p.L311= | Silent (SNP) | VAF 154/295 reads (52%) | called by muse, mutect2, varscan2
- HGF | c.1905T>C p.Y635= | Silent (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.663G>T p.G221= | Silent (SNP) | VAF 59/100 reads (59%) | called by muse, mutect2, varscan2
- MAD2L1BP | c.189T>C p.P63= | Silent (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- MUC4 | c.15846G>T p.G5282= (on ENST00000463781 / NM_018406.7; = p.G1046= on NM_004532.6) | Silent (SNP) | VAF 43/129 reads (33%) | called by muse, mutect2, varscan2
- MYO1F | c.2088T>C p.F696= | Silent (SNP) | VAF 102/225 reads (45%) | called by muse, mutect2, varscan2
- NAALADL2 | c.417G>A p.G139= | Silent (SNP) | VAF 55/258 reads (21%) | catalogued as COSV70795042; called by muse, mutect2, varscan2
- OR4A15 | c.219T>C p.T73= | Silent (SNP) | VAF 87/99 reads (88%) | catalogued as rs561773087; called by muse, mutect2, varscan2
- OR9A4 | c.234C>T p.P78= | Silent (SNP) | VAF 68/148 reads (46%) | catalogued as rs1038085426, COSV71884953, COSV71886112; called by muse, mutect2, varscan2
- PHEX | c.1998G>A p.Q666= | Silent (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- SLITRK2 | c.510G>T p.L170= | Silent (SNP) | VAF 55/127 reads (43%) | called by muse, mutect2, varscan2
- SNAPC4 | c.4302T>A p.G1434= | Silent (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- UNC5D | c.2796C>T p.L932= | Silent (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- VEGFD | c.948C>T p.D316= | Silent (SNP) | VAF 65/167 reads (39%) | called by muse, mutect2, varscan2
- ZNF425 | c.996T>C p.C332= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, varscan2
- DST | c.4297-2073T>G | Intron (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8698T>C | Intron (SNP) | VAF 38/41 reads (93%) | catalogued as rs1306964025; called by muse, mutect2, varscan2
- WASF4P | n.1248dup | RNA (INS) | VAF 17/33 reads (52%) | called by mutect2, pindel, varscan2
